Somatic mutation profile of tumor specimen TCGA-3X-AAVB-01A (aliquot TCGA-3X-AAVB-01A-31D-A417-09) from TCGA case TCGA-3X-AAVB, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IVB; Tumor grade: G1; Age at diagnosis: 70.7 years (25,819 days).
Specimen TCGA-3X-AAVB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8691804e-6855-4461-b29f-0d19a377860c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3X-AAVB-10A (Blood Derived Normal), aliquot TCGA-3X-AAVB-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb1b7575-b48e-491b-b72a-86943e73b6d5

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, Frame Shift Del 2, Intron 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 5/10 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACHE | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs747602194; called by muse, mutect2, varscan2
- CDH7 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs760397263, COSV59885790; called by muse, mutect2, varscan2
- CEACAM5 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.794); catalogued as COSV99703919; called by muse, mutect2, varscan2
- KMT2C | c.4541-1G>C p.X1514_splice | Splice Site (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100070545, COSV51405075; called by muse, mutect2, varscan2
- TUBGCP3 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs773635187, COSV56184764; called by muse, mutect2, varscan2
- ZP4 | c.1116C>A p.S372R | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as COSV63910790; called by muse, mutect2
- A1CF | c.247T>C p.Y83H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- ANKRD34A | c.596T>G p.M199R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CKS1B | c.167A>T p.H56L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CPNE9 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- EFCAB5 | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- FLNA | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HTATSF1 | c.1899del p.Y634Mfs*143 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | called by mutect2, pindel, varscan2
- ITK | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAA35 | c.1632A>T p.Q544H | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- NEURL4 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- SARM1 | c.1231del p.S411Afs*47 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- SLC22A5 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by mutect2, varscan2
- CALN1 | c.57C>T p.D19= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as rs376303075; called by muse, mutect2, varscan2
- RAN | c.282G>A p.S94= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV54563225; called by muse, mutect2, varscan2
- ZMPSTE24 | c.60C>T p.F20= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs765277454; called by muse, mutect2
- BID | c.362-600G>A | Intron (SNP) | VAF 9/33 reads (27%) | catalogued as rs746647273; called by muse, mutect2, varscan2
- TSPEAR | c.1754+293G>A | Intron (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
